Somatic mutation profile of tumor specimen TCGA-19-2623-01A (aliquot TCGA-19-2623-01A-01D-1495-08) from TCGA case TCGA-19-2623, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.3 years (23,835 days).
Specimen TCGA-19-2623-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dd1dc71-59f0-486e-aebd-4581ba954d15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2623-10A (Blood Derived Normal), aliquot TCGA-19-2623-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3d3c86-da43-4101-baf2-b7ee2c52a471

The open-access MAF lists 82 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 37/65 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.2026A>C p.I676L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV55612751; called by muse, mutect2, varscan2
- ASTL | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs145986421; called by muse, mutect2, varscan2
- C15orf48 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs776838309, COSV60223333; called by muse, mutect2, varscan2
- CCL13 | c.204A>C p.K68N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56774691; called by muse, mutect2, varscan2
- CDH18 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV56922062; called by muse, mutect2, varscan2
- CFAP47 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as rs1029862441, COSV52884611; called by muse, mutect2, varscan2
- CYLD | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761903963, COSV61094695; called by muse, mutect2, varscan2
- DGKI | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs779164061, COSV55950318; called by muse, mutect2, varscan2
- DHX8 | c.3590G>A p.R1197H | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs759820680, COSV52253357; called by muse, mutect2, varscan2
- DMD | c.2107C>A p.L703I | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs745972280, COSV55871235; called by muse, mutect2, varscan2
- DNAAF1 | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57577273; called by muse, mutect2, varscan2
- DNAH3 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs759618940, COSV54510249; called by muse, mutect2, varscan2
- ELP1 | c.2603A>T p.D868V | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65897766; called by muse, mutect2, varscan2
- EN2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52083154; called by muse, mutect2, varscan2
- FAM13A | c.2189A>G p.D730G | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1405500572, COSV52002565; called by muse, mutect2, varscan2
- FLT3 | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54047987, COSV54054035; called by muse, mutect2, varscan2
- GABRG1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779053780, COSV54949711, COSV54954783; called by muse, mutect2, varscan2
- GPATCH2 | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.162); catalogued as rs1226939043, COSV65131098; called by muse, mutect2, varscan2
- GTF2H4 | c.131T>G p.V44G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52558884; called by muse, varscan2
- IGHG1 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 144/268 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as rs754412320; called by muse, mutect2, varscan2
- INSR | c.4019C>T p.A1340V | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs200400127; called by muse, mutect2, varscan2
- LGI2 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV66123001; called by muse, mutect2, varscan2
- LRRC7 | c.3255G>C p.R1085S (on ENST00000651989 / NM_001370785.2; = p.R1052S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV50457501; called by muse, mutect2, varscan2
- MGAT4C | c.1180_1184del p.V394Yfs*9 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | catalogued as rs770864945; called by mutect2, pindel, varscan2
- MSR1 | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50511681; called by muse, mutect2, varscan2
- MYH11 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 106/337 reads (31%) | catalogued as COSV55543135; called by muse, mutect2, varscan2
- MYH8 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780844078, COSV67965035; called by muse, mutect2, varscan2
- NEB | c.10762C>T p.Q3588* | Nonsense Mutation (SNP) | VAF 46/376 reads (12%) | catalogued as COSV51400346; called by muse, mutect2, varscan2
- NECTIN1 | c.1404C>G p.Y468* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV50599669; called by muse, mutect2, varscan2
- NLRP1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV52566203; called by muse, mutect2, varscan2
- NLRP5 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs752753307, COSV66764519; called by muse, mutect2, varscan2
- NVL | c.119A>G p.Q40R | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55872525; called by muse, mutect2, varscan2
- NYAP2 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs551391208, COSV56003545; called by muse, mutect2, varscan2
- OR4P4 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58921130, COSV58921916; called by muse, mutect2, varscan2
- OR6N2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs144962739; called by muse, mutect2, varscan2
- PCOLCE2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs532109090, COSV55997408; called by muse, mutect2, varscan2
- PCYT1B | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63264976; called by muse, mutect2, varscan2
- PLA2G4D | c.1538G>T p.R513M | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51820781; called by muse, mutect2, varscan2
- POM121L12 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as COSV68692958, COSV68693988; called by muse, mutect2, varscan2
- PSMA3 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs772232386, COSV53617133; called by muse, mutect2, varscan2
- RERE | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); catalogued as rs748558506, COSV61942071; called by muse, mutect2, varscan2
- SAMSN1 | c.229A>G p.M77V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53471396; called by muse, mutect2, varscan2
- SCAF11 | c.1616C>G p.T539R | Missense Mutation (SNP) | VAF 79/128 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65476590; called by muse, mutect2, varscan2
- SCN10A | c.4282-2A>G p.X1428_splice | Splice Site (SNP) | VAF 44/115 reads (38%) | catalogued as COSV71861335; called by muse, mutect2, varscan2
- SDK1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs145189416; called by muse, mutect2, varscan2
- SMOX | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as rs750147048, COSV53864926; called by muse, mutect2, varscan2
- SPATS2 | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs775186083, COSV58918125; called by muse, mutect2, varscan2
- SPOCK1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as COSV56449216; called by muse, mutect2, varscan2
- SPTAN1 | c.4665G>C p.Q1555H | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV63987114, COSV63989129; called by muse, mutect2, varscan2
- TAF1L | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 143/512 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs748126798, COSV54257964, COSV54261800; called by muse, mutect2, varscan2
- TBX21 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1205690428, COSV51596193; called by muse, mutect2, varscan2
- TRPM3 | c.3404G>A p.R1135K (on ENST00000357533 / NM_001366142.2; = p.R990K on NM_020952.6) | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62585786; called by muse, mutect2, varscan2
- TTC37 | c.3461A>T p.H1154L | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62454786; called by muse, mutect2, varscan2
- TUSC3 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1299241636, COSV65881285; called by muse, mutect2, varscan2
- UACA | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV59855800; called by muse, mutect2, varscan2
- UGT2B4 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1170050355, COSV59316895; called by muse, varscan2
- UPF1 | c.3092G>A p.R1031H (on ENST00000599848 / NM_001297549.2; = p.R1020H on NM_002911.4) | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53196566; called by muse, mutect2, varscan2
- VPS16 | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs377198108; called by muse, mutect2
- ZNF142 | c.4331G>A p.R1444H (on ENST00000411696 / NM_001379660.1; = p.R1244H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs200398690; called by muse, mutect2, varscan2
- ZNF804A | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 92/254 reads (36%) | catalogued as COSV56448686; called by muse, mutect2, varscan2
- OR7C1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 62/233 reads (27%) | called by mutect2, pindel, varscan2
- RB1 | c.1676_1679del p.E559Afs*51 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | called by mutect2, pindel, varscan2
- RFX4 | c.191+2dup p.X64_splice | Splice Site (INS) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- AARS2 | c.2724C>G p.P908= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV55114738; called by muse, mutect2, varscan2
- ATP5F1A | c.753A>G p.Q251= | Silent (SNP) | VAF 111/264 reads (42%) | catalogued as rs1241211540, COSV56360402; called by muse, mutect2, varscan2
- CDCA4 | c.567C>T p.Y189= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as rs745813325, COSV60315153; called by muse, mutect2, varscan2
- COL9A2 | c.1272C>T p.G424= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs777698591, COSV65622784; called by muse, mutect2
- COLEC10 | c.486C>T p.I162= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV60521078; called by muse, mutect2, varscan2
- CYP11B1 | c.1320C>T p.H440= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as rs745610620, COSV52827145; called by muse, mutect2, varscan2
- EFCAB1 | c.243T>C p.D81= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV50618354; called by muse, mutect2, varscan2
- GPR176 | c.1257G>A p.A419= | Silent (SNP) | VAF 120/326 reads (37%) | catalogued as rs758625482, COSV54445130; called by muse, mutect2, varscan2
- HTR6 | c.501C>T p.H167= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV57033099; called by muse, mutect2, varscan2
- MAB21L3 | c.840G>A p.T280= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs148441950; called by muse, mutect2, varscan2
- NLRP2 | c.2664G>C p.L888= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs747841851, COSV54755073; called by muse, mutect2, varscan2
- OR5D16 | c.486G>A p.A162= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as rs201981572, COSV65721949; called by muse, mutect2, varscan2
- SEC16B | c.1209C>T p.P403= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV57625613; called by muse, mutect2, varscan2
- SLC22A2 | c.399G>A p.S133= | Silent (SNP) | VAF 100/216 reads (46%) | catalogued as rs112210325, COSV65266469; called by muse, mutect2, varscan2
- SPX | c.270G>A p.A90= | Silent (SNP) | VAF 135/211 reads (64%) | catalogued as rs547568893, COSV57020748; called by muse, mutect2, varscan2
- TRPM8 | c.2754C>T p.D918= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs759772183, COSV61221996; called by muse, mutect2, varscan2
- ZNF831 | c.1758C>T p.D586= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs968436868, COSV64036891, COSV64041705; called by muse, mutect2, varscan2
- FMN1 | c.2044-1580C>T | Intron (SNP) | VAF 29/106 reads (27%) | catalogued as rs372474008; called by muse, mutect2, varscan2
